Gene-level copy-number profile of tumor specimen TCGA-76-6660-01A from TCGA case TCGA-76-6660, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.7 years (26,913 days).
Specimen TCGA-76-6660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.89a031d0-bdfb-4623-815d-100208070aad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-76-6660-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e578cb10-da0f-4a7a-a528-670bf5e98a22

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 1: 15; copy number 2: 2,050; copy number 3: 10,752; copy number 4: 34,840; copy number 5: 4,662; copy number 6: 7,008; copy number 7: 221; copy number 8: 1; copy number 9: 17; copy number 10: 34; copy number 11: 3; copy number 13: 10; copy number 22: 54; copy number 24: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-76-6660-01A-11D-1842-01): tumor purity 0.75, ploidy 4.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–25,089,151, 84 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 181 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:179,794,958–180,037,053, 1 gene, copy number 24 (within-gene range 4–24): PEX5L.
- chr3:179,875,376–184,457,891, 116 genes, copy number 22–24 (broad region; genes not listed).
- chr12:24,704,503–25,250,936, 17 genes, copy number 9 (within-gene range 6–9): AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:43,353,866–43,572,038, 3 genes, copy number 11: ADAMTS20, AC090525.1, AC090525.2.
- chr12:51,590,266–52,309,163, 34 genes, copy number 10 (within-gene range 4–10): SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN, NR4A1, NR4A1AS, ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1, LINC00592, KRT80, LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2.
- chr12:68,746,125–68,971,570, 10 genes, copy number 13: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
